Somatic mutation profile of tumor specimen TCGA-14-1395-01B (aliquot TCGA-14-1395-01B-11D-1845-08) from TCGA case TCGA-14-1395, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 52.7 years (19,237 days).
Specimen TCGA-14-1395-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cf0789d7-b445-4814-8fba-f6d7a7dcdd1e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-14-1395-10A (Blood Derived Normal), aliquot TCGA-14-1395-10A-01D-1845-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7f1428fe-002e-4394-b60e-9af1049fa583

The open-access MAF lists 54 somatic variants for this specimen: 40 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 13, Frame Shift Del 4, Nonsense Mutation 3, Frame Shift Ins 1, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.548del p.K183Rfs*16 | Frame Shift Del (DEL) | VAF 58/82 reads (71%) | catalogued as rs1554900593, COSV64301859; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ACOT11 | c.1715G>A p.R572H | Missense Mutation (SNP) | VAF 9/31 reads (29%) | catalogued as rs377475734; called by muse, mutect2, varscan2
- CA12 | c.1060G>A p.A354T | Missense Mutation (SNP) | VAF 49/102 reads (48%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.148); catalogued as rs756817698, COSV51607218, COSV99458724; called by muse, mutect2, varscan2
- CABIN1 | c.3373G>A p.V1125I | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs148592192; called by muse, mutect2, varscan2
- CDH18 | c.583G>A p.A195T | Missense Mutation (SNP) | VAF 47/113 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs759064016, COSV56914916, COSV56935577; called by muse, mutect2, varscan2
- CFHR5 | c.638A>T p.Q213L | Missense Mutation (SNP) | VAF 53/105 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as COSV56825606; called by muse, mutect2, varscan2
- COL5A1 | c.2485-1G>T p.X829_splice | Splice Site (SNP) | VAF 28/30 reads (93%) | catalogued as COSV65672780; called by muse, mutect2, varscan2
- CPN2 | c.1633C>T p.P545S | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.037); catalogued as COSV60471183; called by muse, mutect2
- DNPEP | c.1184C>T p.A395V | Missense Mutation (SNP) | VAF 116/270 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs201204134, COSV56111504; called by muse, mutect2, varscan2
- EGFR | c.685A>T p.S229C | Missense Mutation (SNP) | VAF 1997/2567 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV51827895; called by muse, mutect2, varscan2
- FAM241A | c.283C>T p.R95* | Nonsense Mutation (SNP) | VAF 97/209 reads (46%) | catalogued as rs1439095287, COSV59037959; called by muse, mutect2, varscan2
- GABRR2 | c.767C>T p.T256M | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs781232140, COSV68765816; called by muse, mutect2, varscan2
- GRIN2D | c.1636C>T p.R546C | Missense Mutation (SNP) | VAF 50/120 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54378111; called by muse, mutect2, varscan2
- HMCN1 | c.3040T>C p.W1014R | Missense Mutation (SNP) | VAF 22/205 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54924015; called by muse, mutect2, varscan2
- HOOK2 | c.1865C>T p.A622V | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs751517458, COSV53403249, COSV53404456; called by muse, mutect2, varscan2
- KIF26A | c.2698C>T p.R900* | Nonsense Mutation (SNP) | VAF 6/22 reads (27%) | catalogued as rs1307276334, COSV59468268, COSV59468873; called by muse, mutect2, varscan2
- KRT20 | c.328G>A p.A110T | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT tolerated (0.97); PolyPhen benign (0.02); catalogued as COSV51425662; called by muse, mutect2, varscan2
- LPXN | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.968); catalogued as COSV67717798; called by muse, mutect2, varscan2
- LRRC31 | c.1486C>T p.R496* | Nonsense Mutation (SNP) | VAF 35/86 reads (41%) | catalogued as rs370737804; called by muse, mutect2, varscan2
- MAP3K21 | c.1822G>C p.E608Q | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.141); catalogued as COSV64042280, COSV64042367, COSV64042524; called by muse, mutect2, varscan2
- MAST3 | c.2771C>G p.S924C | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53224425, COSV53226066; called by muse, mutect2, varscan2
- MFSD6 | c.1126G>T p.G376C | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as COSV55624211; called by muse, mutect2, varscan2
- MTUS2 | c.371C>T p.T124M | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.047); catalogued as rs745418801, COSV70917869, COSV70920544; called by muse, mutect2, varscan2
- OBSCN | c.733C>T p.R245C | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV52735381; called by muse, mutect2, varscan2
- OR2F1 | c.265C>A p.H89N | Missense Mutation (SNP) | VAF 80/345 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.076); catalogued as COSV67331769; called by muse, mutect2, varscan2
- PCDHB16 | c.2197C>T p.P733S | Missense Mutation (SNP) | VAF 91/196 reads (46%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.818); catalogued as COSV53367286; called by muse, mutect2, varscan2
- SLC5A8 | c.506C>T p.T169M | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs755368848, COSV65987085; called by muse, mutect2, varscan2
- SLC9C1 | c.2396C>T p.P799L | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs201824027, COSV99997249; called by muse, mutect2, varscan2
- SORCS3 | c.2171G>A p.R724H | Missense Mutation (SNP) | VAF 39/41 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs770075122, COSV63797058; called by muse, mutect2, varscan2
- TARBP1 | c.3982G>A p.G1328R | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as rs775037936, COSV50195771; called by muse, mutect2, varscan2
- TRHDE | c.2783G>A p.R928Q | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs771688480, COSV53831518; called by muse, mutect2, varscan2
- TRPM2 | c.2422G>A p.A808T | Missense Mutation (SNP) | VAF 122/261 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as rs749888700, COSV55973191; called by muse, mutect2, varscan2
- UGT2B4 | c.1235C>T p.A412V | Missense Mutation (SNP) | VAF 78/171 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV59319013; called by muse, mutect2, varscan2
- ZBTB2 | c.781C>T p.R261W | Missense Mutation (SNP) | VAF 56/109 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs1036759710, COSV57313264; called by muse, mutect2, varscan2
- ZNF569 | c.2024C>T p.S675L | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.921); catalogued as rs545354210, COSV57593482; called by muse, mutect2, varscan2
- ZNF677 | c.388C>A p.H130N | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.108); catalogued as COSV61720991; called by muse, mutect2, varscan2
- CNTN6 | c.2046del p.I683Lfs*11 | Frame Shift Del (DEL) | VAF 28/69 reads (41%) | called by mutect2, pindel, varscan2
- CUBN | c.4937del p.N1646Tfs*12 | Frame Shift Del (DEL) | VAF 54/78 reads (69%) | called by mutect2, pindel, varscan2
- H1-2 | c.272dup p.T92Hfs*15 | Frame Shift Ins (INS) | VAF 73/212 reads (34%) | called by mutect2, pindel, varscan2
- NCOA2 | c.2262_2268del p.K755Lfs*6 | Frame Shift Del (DEL) | VAF 34/109 reads (31%) | called by mutect2, pindel, varscan2
- ABCB11 | c.3573T>A p.A1191= | Silent (SNP) | VAF 42/226 reads (19%) | catalogued as COSV55596521; called by muse, mutect2, varscan2
- AGXT | c.231C>T p.V77= | Silent (SNP) | VAF 38/96 reads (40%) | catalogued as COSV56754826; called by muse, varscan2
- BARX2 | c.381G>A p.T127= | Silent (SNP) | VAF 16/32 reads (50%) | catalogued as rs781012197, COSV55651641; called by muse, mutect2, varscan2
- CEP72 | c.1131C>T p.N377= | Silent (SNP) | VAF 14/27 reads (52%) | catalogued as rs763789184, COSV53795499; called by muse, mutect2, varscan2
- CMC2 | c.132G>A p.L44= | Silent (SNP) | VAF 31/67 reads (46%) | catalogued as COSV54729839, COSV54730506; called by muse, mutect2, varscan2
- DAGLA | c.2631C>T p.D877= | Silent (SNP) | VAF 24/61 reads (39%) | catalogued as rs373392668, COSV57194602; called by muse, mutect2, varscan2
- MAGEC1 | c.1506T>A p.T502= | Silent (SNP) | VAF 133/147 reads (90%) | catalogued as COSV53578059; called by muse, mutect2, varscan2
- OR8G1 | c.357G>A p.A119= | Silent (SNP) | VAF 83/195 reads (43%) | catalogued as rs769418625, COSV58384156; called by muse, mutect2, varscan2
- PLEKHH3 | c.1332C>T p.N444= | Silent (SNP) | VAF 32/65 reads (49%) | catalogued as rs1567958131, COSV52218986; called by muse, mutect2, varscan2
- SLC38A4 | c.84C>T p.I28= | Silent (SNP) | VAF 108/237 reads (46%) | catalogued as rs200652031, COSV56969705; called by muse, mutect2, varscan2
- TMEM132D | c.165C>T p.N55= | Silent (SNP) | VAF 22/50 reads (44%) | catalogued as rs763982639, COSV70615667; called by muse, mutect2, varscan2
- TRIM49 | c.882A>G p.E294= | Silent (SNP) | VAF 15/73 reads (21%) | catalogued as rs751337512, COSV61671482; called by muse, mutect2, varscan2
- ZNF229 | c.2208C>T p.G736= | Silent (SNP) | VAF 21/66 reads (32%) | catalogued as rs777593082, COSV52160763; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65505393 del TT | 5'Flank (DEL) | VAF 25/75 reads (33%) | catalogued as rs1565057267; called by mutect2, pindel, varscan2
